CCDI case PBCNLK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/c07377d4-e29d-4bff-a8c0-bc07b7b7e6e0

Demographics
Sex at birth: female.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Spinal cord; Age at diagnosis: 11.1 years (4,065 days).

Biospecimens (3 samples)
- Sample 0DW6B0: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DW6B8: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DW6BR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
